Somatic mutation profile of tumor specimen ALCH-B1ZI-TTP1-A (aliquot ALCH-B1ZI-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1ZI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.9 years (21,892 days).
Specimen ALCH-B1ZI-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b4e2d88-4d3f-4990-a051-333183daaca5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1ZI-NB1-A (Blood Derived Normal), aliquot ALCH-B1ZI-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90fa196e-4ebd-41be-aade-dbbabe545fcd

The open-access MAF lists 627 somatic variants for this specimen: 417 protein-altering or splice-affecting, 141 silent, 69 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 360, Silent 141, Intron 37, Nonsense Mutation 27, RNA 13, Splice Region 11, 5'Flank 8, Splice Site 7, 3'UTR 7, Frame Shift Del 7, 5'UTR 4, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNRHR | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs369176613, CM1111644; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STAG3 | c.1312C>T p.R438* | Nonsense Mutation (SNP) | VAF 42/464 reads (9%) | catalogued as rs751680143; ClinVar: likely pathogenic; called by muse, mutect2
- ABCB1 | c.1654C>T p.L552F | Missense Mutation (SNP) | VAF 36/484 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865945115; called by muse, mutect2
- ADIPOR1 | c.602C>G p.S201C | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as rs1271585762; called by muse, mutect2, varscan2
- AHNAK2 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs374331573; called by muse, mutect2, varscan2
- ANKRD30A | c.4121T>G p.F1374C (on ENST00000611781; = p.F1318C on NM_052997.2) | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV100654419; called by muse, varscan2
- ARFGEF1 | c.2656G>T p.E886* | Nonsense Mutation (SNP) | VAF 10/124 reads (8%) | catalogued as COSV99143108; called by muse, mutect2
- ARMCX2 | c.1167del p.K390Rfs*17 | Frame Shift Del (DEL) | VAF 42/282 reads (15%) | catalogued as COSV57531431; called by mutect2, pindel, varscan2
- ASXL3 | c.976G>T p.G326* | Nonsense Mutation (SNP) | VAF 21/165 reads (13%) | catalogued as COSV52463849; called by muse, mutect2, varscan2
- ATRX | c.1558G>C p.V520L | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); catalogued as rs1287383551; called by muse, mutect2
- BPI | c.1307T>C p.M436T (on ENST00000262865; = p.M432T on NM_001725.3) | Missense Mutation (SNP) | VAF 21/268 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1382709575; called by muse, mutect2
- C3orf62 | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 32/365 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV99648929; called by muse, mutect2
- C6orf132 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as rs1015415208; called by muse, mutect2, varscan2
- CBLN4 | c.575C>T p.T192M | Missense Mutation (SNP) | VAF 32/354 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1485393101, COSV99290436; called by muse, mutect2
- CBX8 | c.215G>T p.R72L | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV53935593; called by muse, mutect2
- CCDC148 | c.249C>T p.V83= | Splice Region (SNP) | VAF 24/336 reads (7%) | catalogued as COSV51759687; called by muse, mutect2
- CCDC63 | c.362A>G p.D121G | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100370104; called by muse, mutect2, varscan2
- CCDC74B | c.670C>A p.Q224K | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100134243; called by muse, mutect2, varscan2
- CDH9 | c.180C>A p.F60L | Missense Mutation (SNP) | VAF 47/502 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.836); catalogued as COSV99151294; called by muse, mutect2
- CDX2 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as COSV101122713; called by muse, mutect2
- CEP112 | c.848T>C p.V283A | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV67144289; called by muse, mutect2, varscan2
- CNOT6 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56160697; called by muse, mutect2
- CNTNAP2 | c.1390C>G p.L464V | Missense Mutation (SNP) | VAF 34/345 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.021); catalogued as rs1210288150, COSV100665157; called by muse, mutect2, varscan2
- CPNE4 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV101456817; called by muse, mutect2
- CST2 | c.384G>T p.E128D | Missense Mutation (SNP) | VAF 17/295 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.025); catalogued as COSV59030596; called by muse, mutect2
- CTNNA2 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 18/259 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs777032066, COSV63569988, COSV63590877; called by muse, mutect2
- CWF19L2 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as rs1390589221; called by muse, mutect2
- DCC | c.1546C>A p.P516T | Missense Mutation (SNP) | VAF 77/599 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.09); catalogued as rs1030609611; called by muse, varscan2
- DCX | c.175C>A p.R59S | Missense Mutation (SNP) | VAF 44/498 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57568548; called by muse, mutect2
- DHRS12 | c.350A>G p.H117R (on ENST00000444610 / NM_001377930.1; = p.H68R on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.105); catalogued as rs748619422; called by muse, mutect2, varscan2
- DSCAM | c.4105G>A p.E1369K | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.023); catalogued as COSV68029012; called by muse, mutect2
- DZANK1 | c.763G>A p.E255K (on ENST00000262547 / NM_001099407.1; = p.E56K on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV52747480; called by muse, mutect2
- ERICH3 | c.3028G>C p.E1010Q | Missense Mutation (SNP) | VAF 11/203 reads (5%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.7); catalogued as COSV100443193; called by muse, mutect2
- EYA1 | c.131C>T p.T44I | Missense Mutation (SNP) | VAF 44/745 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs774402195; called by muse, mutect2
- FAM47A | c.54del p.K18Nfs*21 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | catalogued as COSV60495452; called by mutect2, pindel*
- FAT4 | c.11177A>G p.D3726G | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.895); catalogued as rs1177352852; called by muse, mutect2
- FBN3 | c.3180G>C p.E1060D | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.331); catalogued as COSV54473765; called by muse, mutect2
- FBXL6 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as rs1554852816; called by muse, mutect2
- FYB2 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as COSV58583677; called by muse, mutect2
- GFRA1 | c.1232C>G p.T411R | Missense Mutation (SNP) | VAF 46/852 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.073); catalogued as COSV62608798; called by muse, mutect2
- GLIS1 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs555262672; called by muse, mutect2
- GPR158 | c.3289G>A p.E1097K | Missense Mutation (SNP) | VAF 46/402 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1281589754, COSV100892548, COSV100894154; called by muse, mutect2, varscan2
- HCN1 | c.982G>C p.D328H | Missense Mutation (SNP) | VAF 36/682 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV57510777; called by muse, mutect2
- HHLA2 | c.1078C>G p.L360V | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV63317807; called by muse, mutect2
- ICE1 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1166787662, COSV56826899; called by muse, mutect2
- IL21R | c.1238G>T p.G413V | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as rs1262514620; called by muse, mutect2
- IMPG2 | c.1463C>G p.S488C | Missense Mutation (SNP) | VAF 13/349 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV51973051, COSV51981498; called by muse, mutect2
- ITGA1 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 23/259 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50896791; called by muse, mutect2
- ITGB2 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV100185917; called by muse, mutect2
- JPH2 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 19/315 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288721821, COSV60696589; ClinVar: uncertain significance; called by muse, mutect2
- KCNH1 | c.857T>A p.L286H | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55069756, COSV55079390, COSV99661871; called by muse, mutect2
- KLHL34 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs750266650; called by muse, mutect2, varscan2
- KMT2D | c.16207C>T p.R5403C | Missense Mutation (SNP) | VAF 21/481 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56448083, COSV56495821; called by muse, mutect2
- KRT82 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as rs143466157; called by muse, varscan2
- LCE1E | c.95A>C p.K32T | Missense Mutation (SNP) | VAF 40/374 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); catalogued as rs1159497765; called by muse, mutect2, varscan2
- LGR4 | c.2415C>A p.N805K | Missense Mutation (SNP) | VAF 41/394 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as rs1252159538; called by muse, mutect2, varscan2
- LILRA2 | c.541T>C p.S181P | Missense Mutation (SNP) | VAF 28/556 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99063641; called by muse, mutect2
- LNX2 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 46/519 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.034); catalogued as rs755370718; called by muse, mutect2
- LRRC66 | c.1332A>C p.Q444H | Missense Mutation (SNP) | VAF 15/402 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV58637706; called by muse, mutect2
- LRRC72 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 15/234 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as rs1284595265; called by muse, mutect2
- MAP3K8 | c.1098A>C p.E366D | Missense Mutation (SNP) | VAF 42/698 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.163); catalogued as COSV53921714; called by muse, mutect2
- MCOLN1 | c.220C>A p.L74M | Missense Mutation (SNP) | VAF 30/397 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as COSV99900536; called by muse, mutect2
- MRC1 | c.2459C>A p.T820N | Missense Mutation (SNP) | VAF 52/800 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs931240741; called by muse, mutect2
- MSR1 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV50528827; called by muse, mutect2, varscan2
- MTRNR2L10 | c.42G>C p.R14S | Missense Mutation (SNP) | VAF 46/290 reads (16%) | PolyPhen benign (0); catalogued as COSV71256964; called by muse, mutect2, varscan2
- MUC3A | c.803C>T p.T268I | Missense Mutation (SNP) | VAF 25/257 reads (10%) | SIFT tolerated, low confidence (0.07); catalogued as rs778354447; called by muse, mutect2
- MXRA5 | c.789C>A p.Y263* | Nonsense Mutation (SNP) | VAF 8/183 reads (4%) | catalogued as COSV54222609; called by muse, mutect2
- MYT1L | c.1696C>A p.H566N | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV67725049; called by muse, mutect2, varscan2
- NALCN | c.2173G>A p.A725T | Missense Mutation (SNP) | VAF 34/444 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs201135494; called by muse, mutect2
- NDNF | c.1600G>A p.G534S | Missense Mutation (SNP) | VAF 22/432 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as rs761593820, COSV104428381; called by muse, mutect2
- NHSL2 | c.1403G>A p.R468K (on ENST00000510661; = p.R834K on NM_001013627.2) | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65452519; called by muse, mutect2
- NISCH | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as rs1213804946, COSV61902644; called by muse, mutect2
- NLGN4X | c.1025C>A p.P342Q | Missense Mutation (SNP) | VAF 36/704 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52014856; called by muse, mutect2
- NPR3 | c.1361C>A p.P454H | Missense Mutation (SNP) | VAF 13/252 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV54094957; called by muse, mutect2
- OR14A16 | c.80T>G p.I27S | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.07); catalogued as COSV62926150; called by muse, mutect2
- OR2A25 | c.725C>A p.S242Y | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68717342; called by muse, mutect2
- OR2L2 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV63562789; called by muse, mutect2
- OR4M1 | c.354G>T p.M118I | Missense Mutation (SNP) | VAF 52/488 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV60063486; called by muse, mutect2
- OSM | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 39/293 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs201503663; called by muse, mutect2, varscan2
- PBX1 | c.219G>A p.M73I | Missense Mutation (SNP) | VAF 16/426 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV61539195; called by muse, mutect2
- PCDHA9 | c.2134G>T p.V712F | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.665); catalogued as rs77145271; called by muse, mutect2
- PCDHGB7 | c.679C>G p.Q227E | Missense Mutation (SNP) | VAF 17/372 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as COSV53928301; called by muse, mutect2
- PDE8B | c.329C>A p.T110N | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs750567358; called by muse, mutect2
- PIAS2 | c.994G>C p.D332H | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100245057; called by muse, mutect2
- PNMA8B | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 52/289 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs771219969; called by muse, mutect2, varscan2
- PRKX | c.248C>A p.P83H | Missense Mutation (SNP) | VAF 96/517 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.962); catalogued as COSV99468826; called by muse, mutect2, varscan2
- PTH2R | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0.014); catalogued as COSV99782988; called by muse, mutect2
- PTPRT | c.2849G>C p.G950A | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62012566; called by muse, varscan2
- PYGB | c.1769-2A>G p.X590_splice | Splice Site (SNP) | VAF 14/156 reads (9%) | catalogued as COSV53816401; called by muse, mutect2
- RABL2B | c.686G>C p.*229Sext*23 | Nonstop Mutation (SNP) | VAF 10/236 reads (4%) | catalogued as COSV100711439; called by muse, mutect2
- REC114 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.621); catalogued as COSV100461322; called by muse, mutect2, varscan2
- REG3G | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 25/389 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV55448847, COSV99709453; called by muse, mutect2
- RGN | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.473); catalogued as COSV60275834; called by muse, mutect2
- RNASE10 | c.84T>A p.H28Q | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs1370783890, COSV99080450; called by muse, mutect2
- ROBO1 | c.356G>C p.R119P | Missense Mutation (SNP) | VAF 34/512 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71391451; called by muse, mutect2
- S1PR1 | c.692G>T p.R231L | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as COSV59513882; called by muse, mutect2
- SDK1 | c.3635G>A p.R1212K | Missense Mutation (SNP) | VAF 12/364 reads (3%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.996); catalogued as COSV67383819; called by muse, mutect2
- SEMA3F | c.337-5C>T | Splice Region (SNP) | VAF 11/98 reads (11%) | catalogued as rs780395946; called by muse, mutect2, varscan2
- SERPINA6 | c.455A>G p.E152G | Missense Mutation (SNP) | VAF 55/644 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV58584938; called by muse, mutect2
- SLC15A5 | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV61362024; called by muse, mutect2, varscan2
- SLC16A10 | c.1118C>A p.S373Y | Missense Mutation (SNP) | VAF 17/242 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64354427; called by muse, mutect2
- SLC6A7 | c.1505G>T p.W502L | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs755120238; called by muse, mutect2, varscan2
- SLCO1B3 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 26/398 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs865852863, COSV53938200; called by muse, mutect2
- SLITRK6 | c.979C>A p.P327T | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs1192823462; called by muse, mutect2
- SPIN2A | c.773C>A p.S258Y | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV66520702; called by mutect2, varscan2
- SPOCK3 | c.635G>T p.R212I | Missense Mutation (SNP) | VAF 30/518 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62732059; called by muse, mutect2
- SPTA1 | c.1162G>T p.E388* | Nonsense Mutation (SNP) | VAF 119/1008 reads (12%) | catalogued as COSV63752272; called by muse, mutect2, varscan2
- STAC | c.428A>G p.K143R | Missense Mutation (SNP) | VAF 20/357 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV56214073; called by muse, mutect2
- STKLD1 | c.1270C>A p.Q424K | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs781926399; called by muse, mutect2
- SYAP1 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 16/321 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.518); catalogued as COSV101204913; called by muse, mutect2
- SYNE1 | c.2321C>T p.T774I (on ENST00000367255 / NM_182961.4; = p.T781I on NM_033071.3) | Missense Mutation (SNP) | VAF 29/450 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV55121121; called by muse, mutect2
- TAOK3 | c.787C>A p.Q263K | Missense Mutation (SNP) | VAF 14/205 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV101183687; called by muse, mutect2
- TBATA | c.644G>T p.R215I | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs2688753; called by muse, mutect2
- TCERG1L | c.1511G>A p.R504K | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV64057274; called by muse, mutect2
- TDRD9 | c.1021C>T p.H341Y | Missense Mutation (SNP) | VAF 27/554 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59144284; called by muse, mutect2
- TP53 | c.511del p.E171Rfs*3 | Frame Shift Del (DEL) | VAF 32/202 reads (16%) | catalogued as COSV52671445, COSV52701260, COSV52703282; called by mutect2, pindel, varscan2
- TSR1 | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.198); catalogued as COSV100027104, COSV56787342; called by muse, mutect2, varscan2
- TTN | c.2135C>G p.A712G (on ENST00000591111; = p.A666G on NM_003319.4) | Missense Mutation (SNP) | VAF 39/343 reads (11%) | PolyPhen probably damaging (0.996); catalogued as COSV104413474; called by muse, mutect2, varscan2
- USH2A | c.15001G>A p.E5001K | Missense Mutation (SNP) | VAF 46/665 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs750887508, COSV56357272; called by muse, mutect2
- USP7 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as rs1372127093; called by mutect2, varscan2
- UTP14C | c.1109C>G p.P370R | Missense Mutation (SNP) | VAF 18/486 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs1373260811; called by muse, mutect2
- XAGE3 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 18/546 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.225); catalogued as COSV60569290; called by muse, mutect2
- ZBTB22 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV56471205; called by muse, mutect2, varscan2
- ZNF407 | c.4487A>T p.D1496V | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs747688722; called by muse, mutect2, varscan2
- ZNF441 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 16/211 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV63540248; called by muse, mutect2
- ZNF583 | c.1519C>G p.L507V | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52404014; called by muse, mutect2
- ZNF99 | c.1476G>A p.W492* | Nonsense Mutation (SNP) | VAF 29/416 reads (7%) | catalogued as rs771921357; called by muse, mutect2
- ZNHIT2 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.833); catalogued as COSV54204280, COSV54205392, COSV54205400; called by muse, mutect2
- AASDH | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- ABCC12 | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 49/380 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ABCC6 | c.594G>C p.Q198H | Missense Mutation (SNP) | VAF 12/307 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- ABCC8 | c.3017C>T p.S1006F | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.323); called by muse, mutect2
- ABCG8 | c.516G>C p.Q172H | Missense Mutation (SNP) | VAF 28/455 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); called by muse, mutect2
- AC244197.3 | c.-2027G>A | Splice Region (SNP) | VAF 12/227 reads (5%) | called by muse, mutect2
- ACSS3 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2
- ACTRT1 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 9/232 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.097); called by muse, mutect2
- ADAMTS17 | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 70/589 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ADAMTSL1 | c.604dup p.D202Gfs*2 | Frame Shift Ins (INS) | VAF 46/432 reads (11%) | called by mutect2, pindel, varscan2
- ADCY5 | c.3428T>A p.V1143E | Missense Mutation (SNP) | VAF 55/479 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRD1 | c.1091A>C p.N364T | Missense Mutation (SNP) | VAF 33/331 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ADGRG4 | c.4399T>C p.S1467P | Missense Mutation (SNP) | VAF 26/512 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2
- ADGRG4 | c.7161dup p.A2388Sfs*2 | Frame Shift Ins (INS) | VAF 12/145 reads (8%) | called by mutect2, pindel
- AGAP3 | c.1532C>G p.S511C (on ENST00000622464; = p.S547C on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.105); called by muse, mutect2
- AHNAK2 | c.11281G>A p.D3761N | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.714); called by muse, mutect2
- AK9 | c.2200G>T p.E734* | Nonsense Mutation (SNP) | VAF 14/109 reads (13%) | called by muse, mutect2, varscan2
- AKAP3 | c.1505A>C p.N502T | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- AL031681.2 | c.3229C>T p.H1077Y | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.106); called by muse, mutect2
- ALG13 | c.1204G>T p.G402* | Nonsense Mutation (SNP) | VAF 22/260 reads (8%) | called by muse, mutect2
- ALG13 | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 22/255 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.178); called by muse, mutect2
- AMACR | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 44/492 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.089); called by muse, mutect2
- AMY2A | c.59A>G p.N20S | Missense Mutation (SNP) | VAF 16/608 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.5951G>A p.S1984N | Missense Mutation (SNP) | VAF 11/230 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2
- ANKRD17 | c.4138G>C p.D1380H | Missense Mutation (SNP) | VAF 20/481 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANKRD30BL | c.226C>A p.L76I | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- APOB | c.1032A>C p.R344S | Missense Mutation (SNP) | VAF 18/498 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- APOBR | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- ARHGAP28 | c.94C>A p.R32S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ARHGAP30 | c.534G>A p.L178= | Splice Region (SNP) | VAF 14/230 reads (6%) | called by muse, mutect2
- ARHGAP35 | c.3038C>T p.S1013F | Missense Mutation (SNP) | VAF 18/561 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.6); called by muse, mutect2
- ARMCX5-GPRASP2 | c.904A>T p.R302W | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASB2 | c.700G>T p.G234* | Nonsense Mutation (SNP) | VAF 20/115 reads (17%) | called by muse, mutect2, varscan2
- ASTN1 | c.788A>G p.D263G | Missense Mutation (SNP) | VAF 18/285 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.52); called by muse, mutect2
- ATG16L1 | c.952T>C p.F318L (on ENST00000392017 / NM_030803.7; = p.F299L on NM_017974.4) | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- ATP12A | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 11/209 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BCL9L | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 22/334 reads (7%) | called by muse, mutect2
- BIN1 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 37/358 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BMS1 | c.1465G>C p.E489Q | Missense Mutation (SNP) | VAF 24/528 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.123); called by muse, mutect2
- C10orf90 | c.100T>G p.S34A | Missense Mutation (SNP) | VAF 21/306 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.025); called by muse, mutect2
- C12orf71 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by muse, mutect2
- C3orf20 | c.2352G>T p.L784= | Splice Region (SNP) | VAF 14/188 reads (7%) | called by muse, mutect2
- CACNA1E | c.3319G>A p.D1107N | Missense Mutation (SNP) | VAF 38/250 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA2D1 | c.178-2A>G p.X60_splice | Splice Site (SNP) | VAF 21/438 reads (5%) | called by muse, mutect2
- CCDC136 | c.579G>C p.E193D | Missense Mutation (SNP) | VAF 15/245 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2
- CCDC168 | c.10891C>T p.L3631F | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- CCDC68 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 13/213 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCER1 | c.1035G>T p.E345D | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- CCL16 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD2 | c.791A>C p.K264T | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- CDC42BPA | c.2356C>T p.L786F | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2
- CDH2 | c.569A>C p.N190T | Missense Mutation (SNP) | VAF 7/191 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2
- CDH20 | c.2020G>T p.D674Y | Missense Mutation (SNP) | VAF 37/309 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH24 | c.1374G>T p.W458C | Missense Mutation (SNP) | VAF 65/394 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- CDH5 | c.1763A>G p.E588G | Missense Mutation (SNP) | VAF 38/824 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.344); called by muse, mutect2
- CDH8 | c.835A>C p.S279R | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.022); called by muse, mutect2
- CEP63 | c.441+8C>T | Splice Region (SNP) | VAF 15/267 reads (6%) | called by muse, mutect2
- CERK | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 21/249 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.259); called by muse, mutect2
- CHODL | c.176T>C p.L59P | Missense Mutation (SNP) | VAF 27/542 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.249); called by muse, mutect2
- CLCN4 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- CLSTN2 | c.2831C>G p.A944G | Missense Mutation (SNP) | VAF 45/348 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, varscan2
- CNKSR2 | c.1247A>C p.E416A | Missense Mutation (SNP) | VAF 35/274 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- COBL | c.854T>C p.L285P | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COCH | c.653C>A p.P218H (on ENST00000216361 / NM_001347720.1; = p.P153H on NM_004086.3) | Missense Mutation (SNP) | VAF 75/809 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2
- COL4A6 | c.2590G>A p.G864R | Missense Mutation (SNP) | VAF 16/412 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- COL6A5 | c.3815T>C p.L1272P | Missense Mutation (SNP) | VAF 13/384 reads (3%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.548); called by muse, mutect2
- CPA1 | c.797C>A p.A266D | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2
- CPD | c.631_640del p.S211Afs*49 | Frame Shift Del (DEL) | VAF 30/162 reads (19%) | called by mutect2, pindel*, varscan2
- CPN1 | c.787G>T p.G263* | Nonsense Mutation (SNP) | VAF 30/524 reads (6%) | called by muse, mutect2
- CSMD2 | c.1603T>G p.S535A | Missense Mutation (SNP) | VAF 14/267 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.403); called by muse, mutect2
- CTNNA3 | c.1751C>A p.T584K | Missense Mutation (SNP) | VAF 21/233 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.345); called by muse, mutect2
- CTPS2 | c.967C>A p.H323N | Missense Mutation (SNP) | VAF 88/482 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTTNBP2 | c.3220G>A p.D1074N | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.388); called by muse, mutect2
- DAAM2 | c.3185C>T p.A1062V (on ENST00000274867 / NM_001201427.2; = p.A1061V on NM_015345.3) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DDIT4 | c.356T>C p.M119T | Missense Mutation (SNP) | VAF 26/348 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); called by muse, mutect2
- DDR2 | c.2123A>T p.H708L | Missense Mutation (SNP) | VAF 81/618 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGKK | c.2225A>C p.K742T | Missense Mutation (SNP) | VAF 28/754 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2
- DHX30 | c.513G>C p.E171D (on ENST00000445061 / NM_138615.3; = p.E132D on NM_014966.3) | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); called by muse, mutect2
- DIAPH2 | c.2195G>A p.R732K | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DIP2A | c.1805G>T p.R602L | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- DLX2 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- DNAAF1 | c.575-1G>A p.X192_splice | Splice Site (SNP) | VAF 15/422 reads (4%) | called by muse, mutect2
- DNAH7 | c.11234C>T p.S3745L | Missense Mutation (SNP) | VAF 15/266 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.06); called by muse, mutect2
- DNAH9 | c.10729G>C p.V3577L | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- DSTYK | c.2488G>T p.D830Y | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EGF | c.2701G>C p.E901Q | Missense Mutation (SNP) | VAF 30/544 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.776); called by muse, mutect2
- EGLN1 | c.823A>T p.S275C | Missense Mutation (SNP) | VAF 81/560 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- EIF3F | c.938A>C p.N313T | Missense Mutation (SNP) | VAF 8/205 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.035); called by muse, mutect2
- EIF4G1 | c.2386G>A p.G796R (on ENST00000346169 / NM_198241.3; = p.G601R on NM_004953.5) | Missense Mutation (SNP) | VAF 25/242 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELP2 | c.1533G>T p.Q511H | Missense Mutation (SNP) | VAF 32/324 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ENPP2 | c.1674C>A p.Y558* (on ENST00000075322 / NM_001040092.3; = p.Y610* on NM_006209.5) | Nonsense Mutation (SNP) | VAF 49/270 reads (18%) | called by muse, mutect2, varscan2
- ESS2 | c.520A>T p.S174C | Missense Mutation (SNP) | VAF 11/185 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.52); called by muse, mutect2
- FABP9 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 23/461 reads (5%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.97); called by muse, mutect2
- FAM205A | c.1017C>A p.F339L | Missense Mutation (SNP) | VAF 45/331 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- FAT2 | c.6280G>A p.A2094T | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAT4 | c.1753C>G p.P585A | Missense Mutation (SNP) | VAF 34/375 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.157); called by muse, mutect2
- FAT4 | c.8090A>T p.K2697M | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.06); called by muse, mutect2
- FBN1 | c.8024C>T p.P2675L | Missense Mutation (SNP) | VAF 18/436 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by muse, mutect2
- FCGBP | c.715G>T p.V239F | Missense Mutation (SNP) | VAF 32/512 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.963); called by muse, mutect2
- FER | c.1630G>A p.V544I | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.945); called by muse, mutect2
- FHAD1 | c.41T>A p.L14Q | Missense Mutation (SNP) | VAF 10/310 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FMN2 | c.2491C>A p.H831N | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- FSHR | c.1818A>C p.K606N | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- FXR1 | c.45C>G p.F15L | Missense Mutation (SNP) | VAF 27/406 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- GABRG2 | c.754G>T p.G252C (on ENST00000361925 / NM_001375343.1; = p.G212C on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/398 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GAD1 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 28/694 reads (4%) | called by muse, mutect2
- GANAB | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2
- GJA10 | c.1561G>T p.D521Y | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.146); called by muse, mutect2
- GLS | c.891del p.N298Mfs*19 | Frame Shift Del (DEL) | VAF 56/508 reads (11%) | called by mutect2, pindel, varscan2
- GOLGA1 | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 21/376 reads (6%) | called by muse, mutect2
- GPC6 | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 41/658 reads (6%) | called by muse, mutect2
- GPM6B | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 78/397 reads (20%) | called by muse, mutect2, varscan2
- GRIPAP1 | c.2348C>A p.P783Q | Missense Mutation (SNP) | VAF 35/306 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GRM2 | c.2500C>A p.R834S | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- HADH | c.18G>T p.R6S | Missense Mutation (SNP) | VAF 42/456 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.212); called by muse, mutect2
- HARBI1 | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 51/371 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HEPACAM | c.852G>C p.Q284H | Missense Mutation (SNP) | VAF 28/498 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.862); called by muse, mutect2
- HEPACAM | c.716G>C p.S239T | Missense Mutation (SNP) | VAF 34/702 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); called by muse, mutect2
- HOXB13 | c.316C>A p.L106M | Missense Mutation (SNP) | VAF 55/274 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- IGKV1-6 | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 23/829 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- IGSF1 | c.3876-1G>C p.X1292_splice | Splice Site (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- IL5RA | c.1177A>T p.K393* | Nonsense Mutation (SNP) | VAF 16/242 reads (7%) | called by muse, mutect2
- IRS4 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- JMJD1C | c.1469C>G p.T490S | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- JPH2 | c.873C>G p.Y291* | Nonsense Mutation (SNP) | VAF 44/429 reads (10%) | called by muse, mutect2
- KCNC2 | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated, low confidence (0.46); PolyPhen probably damaging (0.975); called by muse, mutect2
- KCNJ5 | c.626C>A p.S209Y | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNN2 | c.1585A>C p.S529R (on ENST00000264773; = p.S741R on NM_021614.4) | Missense Mutation (SNP) | VAF 44/825 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.04); called by muse, mutect2
- KIAA1549L | c.4100C>A p.P1367H (on ENST00000321505; = p.P1664H on NM_012194.3) | Missense Mutation (SNP) | VAF 27/324 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIAA1671 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2
- KIF17 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2
- KMT2D | c.14630G>A p.S4877N | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- KRT76 | c.942A>C p.E314D | Missense Mutation (SNP) | VAF 17/421 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.734); called by muse, mutect2
- KRT85 | c.1086G>C p.K362N | Missense Mutation (SNP) | VAF 41/284 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- L1CAM | c.694A>T p.T232S | Missense Mutation (SNP) | VAF 65/397 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LAMA4 | c.5115C>G p.V1705= (on ENST00000230538 / NM_001105206.3; = p.V1698= on NM_002290.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 36/624 reads (6%) | called by muse, mutect2
- LANCL3 | c.536G>C p.C179S | Missense Mutation (SNP) | VAF 42/375 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- LPAR4 | c.499C>T p.L167F | Missense Mutation (SNP) | VAF 22/528 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.199); called by muse, mutect2
- LRRC7 | c.712C>A p.P238T (on ENST00000651989 / NM_001370785.2; = p.P205T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/574 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- LRRC7 | c.1050G>T p.E350D (on ENST00000651989 / NM_001370785.2; = p.E317D on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/501 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2
- LTBP4 | c.295C>A p.P99T (on ENST00000308370 / NM_001042544.1; = p.P62T on NM_003573.2) | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MAOA | c.765C>G p.I255M | Missense Mutation (SNP) | VAF 64/573 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- MAP2 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.138); called by muse, mutect2
- MAP2 | c.3099G>T p.K1033N | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.575); called by muse, mutect2
- MCOLN3 | c.397-1G>T p.X133_splice | Splice Site (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- MEOX2 | c.696A>C p.K232N | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MRC1 | c.3425C>A p.A1142E | Missense Mutation (SNP) | VAF 128/835 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- MROH7 | c.2881T>A p.C961S | Missense Mutation (SNP) | VAF 6/145 reads (4%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.801); called by muse, mutect2
- MS4A4E | c.387G>C p.L129F | Missense Mutation (SNP) | VAF 8/236 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); called by muse, mutect2
- MSANTD2 | c.644_646del p.I215del | In Frame Del (DEL) | VAF 58/452 reads (13%) | called by pindel, varscan2
- MTF1 | c.925C>T p.H309Y | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2
- MTUS2 | c.2023A>C p.T675P | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- MUC16 | c.42870C>A p.F14290L | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated, low confidence (0.69); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- MXRA5 | c.2759C>G p.P920R | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.021); called by muse, mutect2
- MXRA5 | c.2543T>G p.L848R | Missense Mutation (SNP) | VAF 14/363 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2
- MYH6 | c.1441T>G p.F481V | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2
- MYO5A | c.2254G>T p.A752S | Missense Mutation (SNP) | VAF 78/692 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- MYT1L | c.2563C>T p.P855S | Missense Mutation (SNP) | VAF 30/557 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.337); called by muse, mutect2
- NAA30 | c.607A>T p.R203W | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2
- NCAPD2 | c.2197C>T p.Q733* | Nonsense Mutation (SNP) | VAF 18/296 reads (6%) | called by muse, mutect2
- NCKAP5 | c.4294C>T p.Q1432* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- NDC1 | c.436C>G p.P146A | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); called by muse, mutect2
- NID2 | c.1176A>C p.R392S | Missense Mutation (SNP) | VAF 14/438 reads (3%) | SIFT tolerated (0.43); PolyPhen benign (0.02); called by muse, mutect2
- NLGN2 | c.1679C>A p.T560N | Missense Mutation (SNP) | VAF 47/318 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- NLGN4X | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NLRP11 | c.1456T>A p.S486T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NLRP3 | c.2740C>G p.H914D | Missense Mutation (SNP) | VAF 48/458 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NODAL | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 64/548 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NPAP1 | c.1786A>G p.R596G | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- NPHP4 | c.3198G>T p.Q1066H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NT5E | c.151T>G p.C51G | Missense Mutation (SNP) | VAF 49/347 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NTRK3 | c.1034C>A p.S345Y | Missense Mutation (SNP) | VAF 56/320 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- NXF3 | c.687C>A p.Y229* | Nonsense Mutation (SNP) | VAF 15/202 reads (7%) | called by muse, mutect2
- OR2A25 | c.724T>A p.S242T | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR2AG2 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 43/559 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2
- OR51T1 | c.265T>A p.F89I | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.334); called by muse, mutect2
- ORC4 | c.74G>T p.R25L | Missense Mutation (SNP) | VAF 21/331 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OSBPL6 | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 22/458 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.401); called by muse, mutect2
- OTOF | c.1804-2A>C p.X602_splice | Splice Site (SNP) | VAF 35/297 reads (12%) | called by muse, mutect2, varscan2
- OTX1 | c.125G>C p.R42P | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PABPC1 | c.878G>T p.G293V | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- PALB2 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCCA | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by mutect2, varscan2
- PCDH17 | c.1338C>A p.D446E | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDH19 | c.965G>T p.G322V | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDH9 | c.1339C>A p.P447T | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHB8 | c.2219T>C p.V740A | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.362); called by muse, mutect2
- PCNT | c.5164G>A p.E1722K | Missense Mutation (SNP) | VAF 9/230 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- PCSK1N | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- PDX1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 14/331 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); called by muse, mutect2
- PDZD4 | c.359C>G p.A120G | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.062); called by muse, varscan2
- PGRMC1 | c.260del p.P87Rfs*14 | Frame Shift Del (DEL) | VAF 21/222 reads (9%) | called by mutect2, pindel, varscan2
- PI4KA | c.4052+6G>T | Splice Region (SNP) | VAF 23/142 reads (16%) | called by muse, mutect2, varscan2
- PIKFYVE | c.5148C>G p.I1716M | Missense Mutation (SNP) | VAF 19/580 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by muse, mutect2
- PKHD1 | c.1958C>G p.P653R | Missense Mutation (SNP) | VAF 29/444 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2
- PLPP4 | c.430A>T p.S144C | Missense Mutation (SNP) | VAF 59/230 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLPPR5 | c.262T>G p.F88V | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2
- PLXNA3 | c.4504A>T p.S1502C | Missense Mutation (SNP) | VAF 31/255 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- POLR3B | c.2866G>C p.G956R | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PPARA | c.140G>C p.G47A | Missense Mutation (SNP) | VAF 21/484 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.033); called by muse, mutect2
- PPP4R2 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 19/367 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.18); called by muse, mutect2
- PRKCG | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 29/298 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRRC1 | c.379G>T p.G127C | Missense Mutation (SNP) | VAF 19/280 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); called by muse, mutect2
- PRUNE2 | c.5836G>C p.G1946R | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.278); called by muse, mutect2
- PTGDR | c.417C>G p.F139L | Missense Mutation (SNP) | VAF 25/281 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.401); called by muse, mutect2
- QARS1 | c.452-6T>G | Splice Region (SNP) | VAF 13/298 reads (4%) | called by muse, mutect2
- R3HDM2 | c.1042A>T p.S348C | Missense Mutation (SNP) | VAF 47/413 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RAB3B | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.4); called by muse, varscan2
- RASAL3 | c.2374C>T p.R792C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.251); called by muse, mutect2
- RBMXL2 | c.1106G>T p.G369V | Missense Mutation (SNP) | VAF 68/446 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- RELN | c.7210G>A p.G2404R | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- REPS2 | c.1507A>T p.S503C | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2
- RGL3 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.013); called by muse, mutect2
- RGS12 | c.610C>G p.H204D | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2
- RHOBTB3 | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 43/672 reads (6%) | called by muse, mutect2
- RHOF | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 16/490 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.194); called by muse, mutect2
- RNF175 | c.170T>C p.L57S | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- RPL10 | c.467A>C p.K156T | Missense Mutation (SNP) | VAF 26/636 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2
- RPL36A-HNRNPH2 | c.335C>G p.P112R | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.908); called by muse, varscan2
- RTP5 | c.1170G>T p.K390N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- SARM1 | c.1261C>G p.L421V | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SAXO1 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 49/302 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SCN4A | c.4826G>T p.S1609I | Missense Mutation (SNP) | VAF 41/356 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- SERPINB4 | c.195C>A p.N65K | Missense Mutation (SNP) | VAF 55/517 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SFMBT2 | c.496A>G p.R166G | Missense Mutation (SNP) | VAF 21/359 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.881); called by muse, mutect2
- SGIP1 | c.72T>C p.S24= | Splice Region (SNP) | VAF 8/186 reads (4%) | called by muse, mutect2
- SI | c.5087C>A p.P1696Q | Missense Mutation (SNP) | VAF 53/632 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SKOR2 | c.97C>A p.H33N | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); called by muse, mutect2
- SLC13A5 | c.1429G>T p.A477S | Missense Mutation (SNP) | VAF 23/298 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.913); called by muse, mutect2
- SLC2A9 | c.196G>A p.G66S | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC34A2 | c.2048C>A p.S683* | Nonsense Mutation (SNP) | VAF 82/325 reads (25%) | called by muse, mutect2, varscan2
- SLC6A5 | c.2086A>T p.S696C | Missense Mutation (SNP) | VAF 48/318 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- SLC9A6 | c.1909G>C p.D637H | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2
- SLCO1B1 | c.2051G>T p.G684V | Missense Mutation (SNP) | VAF 26/360 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- SLCO1B3 | c.284A>C p.K95T | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- SLIT2 | c.2851G>T p.G951W | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SMIM10 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 14/438 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- SMS | c.169A>T p.S57C | Missense Mutation (SNP) | VAF 83/435 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- SPAG16 | c.1273A>T p.K425* | Nonsense Mutation (SNP) | VAF 19/358 reads (5%) | called by muse, mutect2
- SPARCL1 | c.1838T>C p.L613P | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPHKAP | c.4793C>A p.P1598H (on ENST00000392056 / NM_001142644.2; = p.P1569H on NM_030623.3) | Missense Mutation (SNP) | VAF 34/268 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SPI1 | c.638G>A p.W213* | Nonsense Mutation (SNP) | VAF 12/288 reads (4%) | called by muse, mutect2
- SPPL2C | c.115T>G p.C39G | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SRPX | c.1394G>C p.*465Sext*15 | Nonstop Mutation (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- STARD9 | c.10256del p.P3419Lfs*85 | Frame Shift Del (DEL) | VAF 18/171 reads (11%) | called by mutect2, pindel, varscan2
- STC1 | c.314C>G p.S105C | Missense Mutation (SNP) | VAF 361/761 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- TAF1 | c.4904C>T p.S1635F (on ENST00000373790 / NM_138923.4; = p.S1656F on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/352 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- TAZ | c.371-3C>A | Splice Region (SNP) | VAF 25/321 reads (8%) | called by muse, mutect2
- TAZ | c.371-1G>A p.X124_splice | Splice Site (SNP) | VAF 26/326 reads (8%) | called by muse, mutect2
- TCF12 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 19/295 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.221); called by muse, mutect2
- TCP11X1 | c.777T>G p.S259R | Missense Mutation (SNP) | VAF 20/325 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.067); called by muse, mutect2
- TCTN1 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 30/277 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TENM2 | c.416G>T p.R139M | Missense Mutation (SNP) | VAF 30/649 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.819); called by muse, mutect2
- TENM4 | c.7550A>G p.K2517R | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.339); called by muse, mutect2
- TEP1 | c.3735G>T p.Q1245H | Missense Mutation (SNP) | VAF 21/276 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.027); called by muse, mutect2
- TEX13C | c.1570C>A p.H524N | Missense Mutation (SNP) | VAF 43/328 reads (13%) | SIFT deleterious (0.02); called by muse, mutect2, varscan2
- TFEB | c.1063G>T p.G355C | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- TGM7 | c.672G>T p.R224S | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TIPRL | c.518G>A p.R173K | Missense Mutation (SNP) | VAF 12/291 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- TOMM70 | c.187C>G p.Q63E | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- TOPAZ1 | c.2516G>A p.R839K | Missense Mutation (SNP) | VAF 13/277 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2
- TRIB1 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.983); called by muse, mutect2
- TRPC5 | c.2096T>C p.F699S | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.446); called by muse, mutect2
- TTC24 | c.375G>T p.L125F | Missense Mutation (SNP) | VAF 73/349 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- TTLL9 | c.924T>A p.S308R | Missense Mutation (SNP) | VAF 15/278 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- TTN | c.101737G>C p.E33913Q (on ENST00000591111; = p.E26489Q on NM_003319.4) | Missense Mutation (SNP) | VAF 6/114 reads (5%) | PolyPhen benign (0.086); called by muse, mutect2
- TTN | c.29422T>C p.F9808L (on ENST00000591111; = p.F8881L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/405 reads (3%) | PolyPhen benign (0.074); called by muse, mutect2
- TULP2 | c.27G>A p.M9I | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- UBR5 | c.6469G>A p.G2157R | Missense Mutation (SNP) | VAF 14/390 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); called by muse, mutect2
- UNC79 | c.3443T>G p.L1148R (on ENST00000393151 / NM_001346218.2; = p.L971R on NM_020818.5) | Missense Mutation (SNP) | VAF 16/235 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- URI1 | c.441T>G p.D147E | Missense Mutation (SNP) | VAF 14/422 reads (3%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.644); called by muse, mutect2
- USH2A | c.2941C>A p.R981S | Missense Mutation (SNP) | VAF 48/341 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VSIG2 | c.935C>G p.S312C | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VSTM2B | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 44/436 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.014); called by muse, mutect2
- VWA5B1 | c.1552G>T p.G518W | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- VWF | c.3734T>C p.V1245A | Missense Mutation (SNP) | VAF 17/472 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- WASHC2A | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 112/711 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- WASHC2A | c.3340A>C p.S1114R | Missense Mutation (SNP) | VAF 38/1334 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.413); called by muse, mutect2
- WDR72 | c.16C>A p.Q6K | Missense Mutation (SNP) | VAF 57/638 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.411); called by muse, mutect2
- WNK2 | c.5691G>T p.R1897S (on ENST00000297954 / NM_001282394.1; = p.R1860S on NM_006648.3) | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.983); called by muse, mutect2
- XIRP2 | c.995C>A p.P332H (on ENST00000628543; = p.P507H on NM_152381.6) | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZBTB37 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.099); called by muse, mutect2
- ZFPM2 | c.805T>G p.L269V | Missense Mutation (SNP) | VAF 22/568 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- ZNF227 | c.1168G>T p.G390C | Missense Mutation (SNP) | VAF 55/307 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZNF451 | c.1743G>C p.L581F | Missense Mutation (SNP) | VAF 18/263 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2
- ZNF536 | c.3413A>C p.K1138T | Missense Mutation (SNP) | VAF 18/584 reads (3%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); called by muse, mutect2
- ZNF585B | c.1669A>G p.K557E | Missense Mutation (SNP) | VAF 19/431 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2
- ZNF585B | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 17/371 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- ZP1 | c.43C>A p.L15M | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.769); called by muse, mutect2
- AADACL4 | c.903C>A p.P301= | Silent (SNP) | VAF 41/169 reads (24%) | called by muse, mutect2, varscan2
- ADNP | c.504G>A p.K168= | Silent (SNP) | VAF 24/318 reads (8%) | called by muse, mutect2
- ADRA1A | c.585G>A p.L195= | Silent (SNP) | VAF 47/715 reads (7%) | called by muse, mutect2
- AFF2 | c.3102C>T p.L1034= | Silent (SNP) | VAF 22/635 reads (3%) | catalogued as rs1181780202; called by muse, mutect2
- AKAP6 | c.5355T>C p.I1785= | Silent (SNP) | VAF 13/296 reads (4%) | catalogued as COSV55206321; called by muse, mutect2
- ARFGEF1 | c.705A>T p.P235= | Silent (SNP) | VAF 32/475 reads (7%) | called by muse, mutect2
- ARHGEF3 | c.903C>T p.I301= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as rs760968805, COSV56322722; called by muse, mutect2
- ARMCX4 | c.483C>A p.T161= (on ENST00000433011; = p.T57= on NM_001256155.2) | Silent (SNP) | VAF 51/444 reads (11%) | called by muse, mutect2, varscan2
- ASB18 | c.585C>T p.A195= | Silent (SNP) | VAF 18/133 reads (14%) | catalogued as rs1054454311; called by muse, mutect2, varscan2
- ATG101 | c.318G>A p.K106= | Silent (SNP) | VAF 23/231 reads (10%) | called by muse, mutect2
- ATG2A | c.1521C>T p.G507= | Silent (SNP) | VAF 29/285 reads (10%) | called by muse, mutect2, varscan2
- ATP23 | c.351C>T p.A117= | Silent (SNP) | VAF 14/278 reads (5%) | catalogued as rs1485745015, COSV55686623; called by muse, mutect2
- ATP2B3 | c.378C>T p.F126= | Silent (SNP) | VAF 26/284 reads (9%) | catalogued as COSV54846469; called by muse, mutect2
- BCORL1 | c.1152C>T p.P384= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs1173172680; called by muse, mutect2, varscan2
- BCORL1 | c.2364C>A p.A788= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as rs984072670, COSV54407562; called by muse, mutect2, varscan2
- BTNL8 | c.261G>T p.L87= | Silent (SNP) | VAF 21/271 reads (8%) | called by muse, mutect2
- C5orf51 | c.24G>T p.V8= | Silent (SNP) | VAF 25/236 reads (11%) | called by muse, mutect2, varscan2
- C9orf131 | c.132A>G p.T44= | Silent (SNP) | VAF 60/584 reads (10%) | called by muse, mutect2
- CACNA1D | c.3297G>A p.T1099= (on ENST00000350061 / NM_001128840.3; = p.T1119= on NM_000720.4) | Silent (SNP) | VAF 48/617 reads (8%) | catalogued as rs151094357, COSV55455644; called by muse, mutect2
- CCDC120 | c.1695G>C p.R565= | Silent (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- CCDC168 | c.9276A>G p.S3092= | Silent (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- CD79B | c.417G>A p.E139= | Silent (SNP) | VAF 30/600 reads (5%) | called by muse, mutect2
- CDH12 | c.708C>T p.L236= | Silent (SNP) | VAF 11/261 reads (4%) | catalogued as COSV101202681; called by muse, mutect2
- CDKL5 | c.1989G>C p.S663= | Silent (SNP) | VAF 75/571 reads (13%) | called by muse, mutect2, varscan2
- CELSR3 | c.8334T>C p.A2778= | Silent (SNP) | VAF 7/106 reads (7%) | called by muse, mutect2
- CNTNAP4 | c.27C>G p.L9= | Silent (SNP) | VAF 16/342 reads (5%) | called by muse, mutect2
- COLEC11 | c.261C>A p.P87= | Silent (SNP) | VAF 21/403 reads (5%) | catalogued as COSV52592636; called by muse, mutect2
- CSMD1 | c.10005A>G p.G3335= (on ENST00000520002; = p.G3334= on NM_033225.6) | Silent (SNP) | VAF 16/154 reads (10%) | called by muse, mutect2
- CSMD1 | c.1893T>C p.D631= (on ENST00000520002; = p.D630= on NM_033225.6) | Silent (SNP) | VAF 58/482 reads (12%) | catalogued as rs770014926; called by muse, mutect2, varscan2
- CT55 | c.444T>A p.G148= | Silent (SNP) | VAF 18/306 reads (6%) | called by muse, mutect2
- CTNNA3 | c.750T>C p.N250= | Silent (SNP) | VAF 20/312 reads (6%) | called by muse, mutect2
- CUBN | c.168G>A p.G56= | Silent (SNP) | VAF 26/642 reads (4%) | called by muse, mutect2
- DIP2C | c.2541G>A p.R847= | Silent (SNP) | VAF 17/235 reads (7%) | called by muse, mutect2
- DNAJC11 | c.594G>A p.A198= | Silent (SNP) | VAF 17/261 reads (7%) | catalogued as rs773363940; called by muse, mutect2
- DOT1L | c.1395G>T p.P465= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV67111639; called by muse, mutect2, varscan2
- DRD5 | c.885C>G p.L295= | Silent (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- DUOX2 | c.4612C>A p.R1538= | Silent (SNP) | VAF 44/537 reads (8%) | catalogued as COSV66532437; called by muse, mutect2
- DYNC1H1 | c.4641G>A p.L1547= | Silent (SNP) | VAF 21/439 reads (5%) | called by muse, mutect2
- ECEL1 | c.1818C>A p.I606= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as rs1284757016; called by muse, mutect2, varscan2
- EFCAB8 | c.1884G>A p.L628= | Silent (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- EIF3A | c.1320G>A p.L440= | Silent (SNP) | VAF 20/397 reads (5%) | called by muse, mutect2
- EN2 | c.879G>A p.Q293= | Silent (SNP) | VAF 16/354 reads (5%) | called by muse, mutect2
- FAM135A | c.558G>A p.V186= (on ENST00000370479 / NM_001351599.1; = p.V143= on NM_020819.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/202 reads (4%) | called by muse, mutect2
- FAM189A2 | c.1263G>T p.A421= | Silent (SNP) | VAF 32/620 reads (5%) | called by muse, mutect2
- FAM47C | c.123G>T p.P41= | Silent (SNP) | VAF 32/295 reads (11%) | catalogued as COSV63725468, COSV63731070; called by muse, mutect2, varscan2
- FAT4 | c.4857C>T p.I1619= | Silent (SNP) | VAF 17/358 reads (5%) | catalogued as COSV67896972; called by muse, mutect2
- FBXL3 | c.447A>T p.R149= | Silent (SNP) | VAF 16/262 reads (6%) | called by muse, mutect2
- FCGR2C | c.639C>G p.V213= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV100912482; called by muse, mutect2
- FGF13 | c.84C>T p.V28= | Silent (SNP) | VAF 15/460 reads (3%) | called by muse, mutect2
- FLG2 | c.6834A>G p.Q2278= | Silent (SNP) | VAF 37/478 reads (8%) | catalogued as COSV66168605, COSV66171573; called by muse, mutect2
- FLT3 | c.2004G>T p.L668= | Silent (SNP) | VAF 26/334 reads (8%) | called by muse, mutect2
- G0S2 | c.126G>A p.L42= | Silent (SNP) | VAF 29/207 reads (14%) | catalogued as rs1199606570; called by muse, mutect2, varscan2
- GABRA1 | c.414C>T p.N138= | Silent (SNP) | VAF 40/554 reads (7%) | catalogued as rs1057522080; ClinVar: likely benign; called by muse, mutect2
- GAREM2 | c.1359C>T p.F453= | Silent (SNP) | VAF 12/202 reads (6%) | called by muse, mutect2
- GLA | c.855C>A p.A285= | Silent (SNP) | VAF 47/330 reads (14%) | called by muse, mutect2, varscan2
- GRM1 | c.1383A>G p.G461= | Silent (SNP) | VAF 40/696 reads (6%) | catalogued as rs771690784; called by muse, mutect2
- HMGN5 | c.606A>G p.R202= | Silent (SNP) | VAF 30/345 reads (9%) | called by muse, mutect2
- ICE1 | c.4740G>A p.Q1580= | Silent (SNP) | VAF 17/212 reads (8%) | called by muse, mutect2
- INTS6L | c.369T>G p.S123= | Silent (SNP) | VAF 26/218 reads (12%) | called by muse, mutect2, varscan2
- ITPKC | c.1812A>G p.E604= | Silent (SNP) | VAF 65/332 reads (20%) | catalogued as rs1256714858; called by muse, mutect2, varscan2
- KALRN | c.864G>A p.L288= | Silent (SNP) | VAF 10/236 reads (4%) | called by muse, mutect2
- KANSL1L | c.1680C>A p.A560= | Silent (SNP) | VAF 60/516 reads (12%) | catalogued as COSV99910781; called by muse, mutect2, varscan2
- KCNB2 | c.1068T>A p.A356= | Silent (SNP) | VAF 9/189 reads (5%) | called by muse, mutect2
- KCNH3 | c.339G>C p.V113= | Silent (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- KCTD19 | c.1524C>A p.I508= | Silent (SNP) | VAF 18/339 reads (5%) | called by muse, mutect2
- KRT40 | c.51G>T p.T17= | Silent (SNP) | VAF 22/178 reads (12%) | catalogued as COSV100898894; called by muse, mutect2, varscan2
- L3MBTL1 | c.597C>T p.A199= (on ENST00000418998 / NM_001377303.1; = p.A109= on NM_015478.7) | Silent (SNP) | VAF 48/405 reads (12%) | catalogued as COSV64230658, COSV64235612; called by muse, mutect2, varscan2
- LCE1B | c.255C>A p.S85= | Silent (SNP) | VAF 24/306 reads (8%) | catalogued as COSV63980036; called by muse, mutect2
- LILRB5 | c.537G>T p.L179= | Silent (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- LIMK1 | c.1200C>A p.I400= | Silent (SNP) | VAF 10/132 reads (8%) | called by muse, mutect2
- LOXHD1 | c.4818C>T p.A1606= | Silent (SNP) | VAF 16/204 reads (8%) | catalogued as rs976758061, COSV56061550; called by muse, mutect2
- LRBA | c.4656G>A p.L1552= | Silent (SNP) | VAF 16/197 reads (8%) | called by muse, mutect2
- LRRC8D | c.981G>T p.A327= | Silent (SNP) | VAF 53/509 reads (10%) | called by muse, mutect2, varscan2
- MME | c.1743C>A p.V581= | Silent (SNP) | VAF 65/596 reads (11%) | called by muse, mutect2, varscan2
- MUC16 | c.41019C>T p.S13673= | Silent (SNP) | VAF 55/342 reads (16%) | catalogued as COSV101109743, COSV66692169; called by muse, mutect2, varscan2
- NFS1 | c.903G>T p.V301= | Silent (SNP) | VAF 24/193 reads (12%) | called by muse, mutect2, varscan2
- NLGN3 | c.189G>A p.L63= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs1416419158; called by muse, mutect2, varscan2
- NUF2 | c.636G>A p.K212= | Silent (SNP) | VAF 25/344 reads (7%) | called by muse, mutect2
- OPRPN | c.444C>A p.T148= | Silent (SNP) | VAF 23/185 reads (12%) | catalogued as COSV68192648; called by muse, mutect2, varscan2
- OR1J2 | c.549C>A p.A183= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV58944942; called by muse, mutect2
- OR1S2 | c.396C>A p.A132= | Silent (SNP) | VAF 41/390 reads (11%) | called by muse, mutect2, varscan2
- OR2A2 | c.741T>G p.V247= | Silent (SNP) | VAF 12/237 reads (5%) | called by muse, mutect2
- OR51I2 | c.841C>T p.L281= | Silent (SNP) | VAF 10/234 reads (4%) | catalogued as rs1290133332; called by muse, mutect2
- OR7D4 | c.801T>A p.S267= | Silent (SNP) | VAF 18/228 reads (8%) | called by muse, mutect2
- OTOG | c.2745G>A p.L915= | Silent (SNP) | VAF 12/214 reads (6%) | called by muse, mutect2
- PARP8 | c.1815A>T p.V605= | Silent (SNP) | VAF 12/286 reads (4%) | called by muse, mutect2
- PASD1 | c.2073G>A p.R691= | Silent (SNP) | VAF 23/630 reads (4%) | called by muse, mutect2
- PCDH17 | c.2919C>G p.L973= | Silent (SNP) | VAF 28/461 reads (6%) | called by muse, mutect2
- PCDH7 | c.1740G>A p.G580= | Silent (SNP) | VAF 25/273 reads (9%) | called by muse, mutect2
- PCDHB11 | c.1128G>A p.G376= | Silent (SNP) | VAF 18/354 reads (5%) | catalogued as COSV61311642; called by muse, mutect2
- PCLO | c.882T>G p.V294= | Silent (SNP) | VAF 28/578 reads (5%) | called by muse, mutect2
- PDE6B | c.1608C>A p.P536= | Silent (SNP) | VAF 55/370 reads (15%) | called by muse, mutect2, varscan2
- PITRM1 | c.1281T>G p.A427= | Silent (SNP) | VAF 11/236 reads (5%) | called by muse, mutect2
- PLXNA4 | c.3909G>T p.L1303= | Silent (SNP) | VAF 10/137 reads (7%) | called by muse, mutect2
- PNMA8B | c.867C>T p.V289= | Silent (SNP) | VAF 51/288 reads (18%) | called by muse, mutect2, varscan2
- POM121L2 | c.1347A>G p.S449= | Silent (SNP) | VAF 26/316 reads (8%) | called by muse, mutect2
- POMC | c.693G>T p.P231= | Silent (SNP) | VAF 10/105 reads (10%) | catalogued as COSV53035332; called by muse, mutect2, varscan2
- PREX1 | c.426C>T p.F142= | Silent (SNP) | VAF 12/146 reads (8%) | catalogued as COSV100906583; called by muse, mutect2
- PRMT5 | c.774C>T p.L258= | Silent (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2
- PROZ | c.231C>G p.V77= | Silent (SNP) | VAF 16/512 reads (3%) | called by muse, mutect2
- PTBP3 | c.1410C>T p.I470= | Silent (SNP) | VAF 48/445 reads (11%) | called by muse, mutect2, varscan2
- PURG | c.705C>A p.A235= | Silent (SNP) | VAF 18/191 reads (9%) | catalogued as COSV99989924; called by muse, mutect2
- RELB | c.375G>T p.P125= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs746034758, COSV99673057; called by muse, mutect2, varscan2
- RNASE7 | c.78C>T p.V26= | Silent (SNP) | VAF 35/352 reads (10%) | called by muse, mutect2
- RTL9 | c.3390T>C p.T1130= | Silent (SNP) | VAF 49/332 reads (15%) | called by muse, mutect2, varscan2
- SAGE1 | c.387A>T p.S129= | Silent (SNP) | VAF 25/340 reads (7%) | called by muse, mutect2
- SBK2 | c.822C>T p.Y274= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
- SEMA5A | c.2157T>C p.S719= | Silent (SNP) | VAF 37/642 reads (6%) | catalogued as rs768610493; called by muse, mutect2
- SEMA6C | c.1935C>A p.L645= | Silent (SNP) | VAF 19/265 reads (7%) | called by muse, mutect2
- SI | c.5088A>G p.P1696= | Silent (SNP) | VAF 54/630 reads (9%) | catalogued as COSV100013645; called by muse, mutect2
- SLC12A2 | c.3585A>T p.P1195= | Silent (SNP) | VAF 20/408 reads (5%) | catalogued as COSV52477178; called by muse, mutect2
- SLC2A12 | c.759C>T p.I253= | Silent (SNP) | VAF 28/331 reads (8%) | catalogued as rs553434141; called by muse, mutect2
- SLC2A6 | c.1479G>A p.Q493= | Silent (SNP) | VAF 18/216 reads (8%) | catalogued as COSV99390093; called by muse, mutect2
- SLC2A6 | c.942C>T p.D314= | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as rs200040212; called by muse, mutect2
- SLC6A3 | c.1524C>T p.I508= | Silent (SNP) | VAF 19/356 reads (5%) | catalogued as rs745668378, COSV54365539; called by muse, mutect2
- SLCO4A1 | c.1362C>G p.V454= | Silent (SNP) | VAF 45/239 reads (19%) | called by muse, mutect2, varscan2
- SMAD9 | c.522C>T p.N174= | Silent (SNP) | VAF 86/849 reads (10%) | catalogued as rs377089593; called by muse, mutect2, varscan2
- SMOC2 | c.384G>T p.T128= | Silent (SNP) | VAF 33/247 reads (13%) | called by muse, mutect2, varscan2
- SNTB1 | c.1383T>C p.N461= | Silent (SNP) | VAF 16/251 reads (6%) | called by muse, mutect2
- SPTA1 | c.6751C>A p.R2251= | Silent (SNP) | VAF 30/252 reads (12%) | called by muse, mutect2, varscan2
- SSU72P8 | c.408G>A p.V136= | Silent (SNP) | VAF 9/191 reads (5%) | called by muse, mutect2
- TBX1 | c.1159C>T p.L387= | Silent (SNP) | VAF 35/255 reads (14%) | called by muse, mutect2, varscan2
- THSD7B | c.525T>A p.P175= | Silent (SNP) | VAF 22/392 reads (6%) | called by muse, mutect2
- TMCO1 | c.375G>A p.E125= (on ENST00000612311 / NM_001256164.1; = p.E74= on NM_019026.6) | Silent (SNP) | VAF 15/424 reads (4%) | called by muse, mutect2
- TMEM8B | c.534G>A p.R178= | Silent (SNP) | VAF 19/126 reads (15%) | called by muse, mutect2, varscan2
- TMTC1 | c.2073A>G p.A691= (on ENST00000539277 / NM_001193451.2; = p.A583= on NM_175861.3) | Silent (SNP) | VAF 26/467 reads (6%) | called by muse, mutect2
- TMTC2 | c.2295G>A p.E765= | Silent (SNP) | VAF 8/186 reads (4%) | catalogued as COSV100338571; called by muse, mutect2
- TRIB2 | c.456A>T p.A152= | Silent (SNP) | VAF 49/570 reads (9%) | called by muse, mutect2
- TRIM28 | c.2427G>T p.L809= | Silent (SNP) | VAF 32/290 reads (11%) | called by muse, mutect2, varscan2
- TRIM42 | c.441C>T p.P147= | Silent (SNP) | VAF 13/344 reads (4%) | called by muse, mutect2
- TRMT1L | c.987G>A p.V329= | Silent (SNP) | VAF 18/544 reads (3%) | catalogued as rs1238623441; called by muse, mutect2
- TROAP | c.2133G>C p.L711= | Silent (SNP) | VAF 12/332 reads (4%) | catalogued as COSV57746058; called by muse, mutect2
- TWNK | c.729C>T p.A243= | Silent (SNP) | VAF 15/174 reads (9%) | catalogued as rs772966824, COSV99272074; called by muse, mutect2
- UNC13D | c.3058C>T p.L1020= | Silent (SNP) | VAF 10/248 reads (4%) | called by muse, mutect2
- USP26 | c.1209A>G p.T403= | Silent (SNP) | VAF 38/277 reads (14%) | called by muse, mutect2, varscan2
- VWA3A | c.747G>T p.L249= | Silent (SNP) | VAF 25/188 reads (13%) | catalogued as rs368919567, COSV67011837; called by muse, mutect2, varscan2
- VWF | c.7047C>A p.T2349= | Silent (SNP) | VAF 38/522 reads (7%) | called by muse, mutect2
- ZBTB20 | c.1080A>T p.T360= (on ENST00000474710 / NM_001164342.2; = p.T287= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- ZNF177 | c.418A>C p.R140= | Silent (SNP) | VAF 7/131 reads (5%) | called by muse, mutect2
- ZNF19 | c.1272T>G p.T424= | Silent (SNP) | VAF 16/417 reads (4%) | called by muse, mutect2
- ZNRF3 | c.1503G>A p.P501= (on ENST00000544604 / NM_001206998.2; = p.P401= on NM_032173.3) | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs749859649, COSV60436661; called by muse, mutect2, varscan2
- AC044798.1 | n.112T>G | RNA (SNP) | VAF 12/339 reads (4%) | called by muse, mutect2
- AC091163.2 | n.572C>T | RNA (SNP) | VAF 26/330 reads (8%) | called by muse, mutect2
- AC093155.3 | c.767-848G>A | Intron (SNP) | VAF 14/262 reads (5%) | called by muse, mutect2
- AC139769.1 | n.214-3892G>T | Intron (SNP) | VAF 48/586 reads (8%) | called by muse, mutect2
- AP001007.2 | n.392C>G | RNA (SNP) | VAF 58/413 reads (14%) | called by muse, mutect2, varscan2
- ATL3 | chr11:63671702 C>A | 5'Flank (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2, varscan2
- BCL2L11 | c.498+3649A>C | Intron (SNP) | VAF 12/372 reads (3%) | called by muse, mutect2
- BLACE | n.1419C>A | RNA (SNP) | VAF 20/169 reads (12%) | called by muse, mutect2
- BRD4 | c.2158+679G>A | Intron (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- C10orf143 | c.69+3890G>C | Intron (SNP) | VAF 47/349 reads (13%) | catalogued as rs781203651; called by muse, mutect2, varscan2
- CBLIF | c.370+15G>A | Intron (SNP) | VAF 40/836 reads (5%) | called by muse, mutect2
- CCNYL2 | n.650G>A | RNA (SNP) | VAF 9/234 reads (4%) | called by muse, mutect2
- CHRNA4 | c.*2413C>A | 3'UTR (SNP) | VAF 41/338 reads (12%) | called by muse, mutect2, varscan2
- COLEC11 | chr2:3595057 T>A | 5'Flank (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- CXCL12 | c.*1965T>A | 3'UTR (SNP) | VAF 9/173 reads (5%) | catalogued as COSV65631950; called by muse, mutect2
- CYB561 | c.-13-541del | Intron (DEL) | VAF 20/152 reads (13%) | called by mutect2, pindel, varscan2
- DNM1P46 | n.275G>A | RNA (SNP) | VAF 16/116 reads (14%) | called by muse, mutect2
- DPP10 | c.61-147023C>T | Intron (SNP) | VAF 10/314 reads (3%) | called by muse, mutect2
- EGFEM1P | n.626C>A | RNA (SNP) | VAF 26/334 reads (8%) | called by muse, mutect2
- EMD | c.-39C>A | 5'UTR (SNP) | VAF 38/242 reads (16%) | called by muse, mutect2, varscan2
- F5 | c.*44C>G | 3'UTR (SNP) | VAF 20/314 reads (6%) | called by muse, mutect2
- FLNA | c.6907+24G>T | Intron (SNP) | VAF 20/405 reads (5%) | called by muse, mutect2
- GARS1 | chr7:30594871 G>T | 5'Flank (SNP) | VAF 34/128 reads (27%) | called by muse, varscan2
- HDAC4 | chr2:239401935 G>T | 5'Flank (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- ISCA1 | c.-34C>T | 5'UTR (SNP) | VAF 32/369 reads (9%) | called by muse, mutect2
- ITGB2 | c.1296+13A>T | Intron (SNP) | VAF 7/172 reads (4%) | catalogued as rs1040932857; called by muse, mutect2
- KIF6 | c.1077+1459A>C | Intron (SNP) | VAF 24/339 reads (7%) | called by muse, mutect2
- LINC00602 | n.806G>T | RNA (SNP) | VAF 15/115 reads (13%) | catalogued as rs1020141811; called by muse, mutect2, varscan2
- LINC00632 | n.104+1979C>T | Intron (SNP) | VAF 34/600 reads (6%) | called by muse, mutect2
- LNPK | c.707-1360C>T | Intron (SNP) | VAF 20/270 reads (7%) | catalogued as rs775809795; called by muse, mutect2
- LRRC27 | chr10:132331796 C>T | 5'Flank (SNP) | VAF 4/46 reads (9%) | catalogued as rs1209235924; called by muse, mutect2
- MARCHF10 | c.383-2407C>A | Intron (SNP) | VAF 33/272 reads (12%) | called by muse, mutect2, varscan2
- METTL16 | n.1071C>G | RNA (SNP) | VAF 26/259 reads (10%) | catalogued as rs775233522; called by muse, mutect2, varscan2
- METTL25 | c.1573-34A>G | Intron (SNP) | VAF 9/181 reads (5%) | catalogued as rs1327308712; called by muse, mutect2
- MIR508 | n.15G>C | RNA (SNP) | VAF 45/397 reads (11%) | called by muse, mutect2, varscan2
- MIR513B | n.50A>T | RNA (SNP) | VAF 18/322 reads (6%) | called by muse, mutect2
- MLLT10 | c.240+17926del | Intron (DEL) | VAF 141/539 reads (26%) | called by mutect2, pindel, varscan2
- MPHOSPH9 | c.2909-9C>G | Intron (SNP) | VAF 16/210 reads (8%) | called by muse, mutect2
- NCOR2 | c.233+22C>T | Intron (SNP) | VAF 21/264 reads (8%) | catalogued as rs1446667292; called by muse, mutect2
- NMRK1 | c.389+51G>T | Intron (SNP) | VAF 7/122 reads (6%) | called by muse, mutect2
- NOTCH2 | c.2479+63G>T | Intron (SNP) | VAF 26/612 reads (4%) | called by muse, mutect2
- NSMF | c.1131+14C>A | Intron (SNP) | VAF 8/79 reads (10%) | catalogued as rs750800160; called by muse, mutect2, varscan2
- NUDT9P1 | n.446A>T | RNA (SNP) | VAF 25/335 reads (7%) | called by muse, mutect2
- PA2G4 | c.-151C>T | 5'UTR (SNP) | VAF 36/612 reads (6%) | catalogued as COSV99916883; called by muse, mutect2
- PKD2 | c.-31C>T | 5'UTR (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- POMT1 | c.1052+48C>T | Intron (SNP) | VAF 7/95 reads (7%) | called by muse, mutect2
- PPP1R1B | chr17:39622131 A>T | 5'Flank (SNP) | VAF 15/541 reads (3%) | called by muse, mutect2
- PPP3CA | chr4:101348731 G>T | 5'Flank (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2
- PRKAG2 | c.1678+33C>T | Intron (SNP) | VAF 9/191 reads (5%) | catalogued as rs1265836047, COSV55223693; called by muse, mutect2
- PTPRO | c.1106-22C>T | Intron (SNP) | VAF 14/119 reads (12%) | catalogued as rs1204265613; called by muse, mutect2, varscan2
- RGS7 | c.*7-33C>G | Intron (SNP) | VAF 30/366 reads (8%) | called by muse, mutect2
- RIC8A | c.727-180C>T | Intron (SNP) | VAF 33/387 reads (9%) | catalogued as rs1381485362; called by muse, mutect2
- SDHC | c.180-1015T>C | Intron (SNP) | VAF 15/373 reads (4%) | called by muse, mutect2
- SGSM2 | c.*736C>T | 3'UTR (SNP) | VAF 11/181 reads (6%) | called by muse, mutect2
- SHISA6 | chr17:11241418 C>A | 5'Flank (SNP) | VAF 18/98 reads (18%) | called by muse, mutect2, varscan2
- SLC25A37 | c.*1797T>C | 3'UTR (SNP) | VAF 4/8 reads (50%) | catalogued as rs1054491322; called by muse, mutect2
- SLC37A2 | c.1490+244T>C | Intron (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- STK32C | c.263-3134C>T | Intron (SNP) | VAF 16/228 reads (7%) | catalogued as rs1187848741; called by muse, mutect2
- SYCE1 | c.271+52C>T | Intron (SNP) | VAF 51/279 reads (18%) | catalogued as rs879885536; called by muse, mutect2, varscan2
- SYT7 | c.215+5256G>A | Intron (SNP) | VAF 40/209 reads (19%) | called by muse, mutect2, varscan2
- TPM3 | c.244-6792G>A | Intron (SNP) | VAF 44/670 reads (7%) | called by muse, mutect2
- U82695.1 | n.1801G>T | RNA (SNP) | VAF 69/463 reads (15%) | called by muse, mutect2, varscan2
- UBE2A | c.126-20C>A | Intron (SNP) | VAF 57/519 reads (11%) | called by muse, mutect2, varscan2
- UBE3B | c.3015+208C>T | Intron (SNP) | VAF 15/144 reads (10%) | catalogued as rs1279567280; called by muse, mutect2, varscan2
- VAPB | c.*1370A>T | 3'UTR (SNP) | VAF 14/256 reads (5%) | called by muse, mutect2
- ZAP70 | c.402+186G>C | Intron (SNP) | VAF 16/198 reads (8%) | called by muse, mutect2
- ZC3HAV1 | c.2096+82G>T | Intron (SNP) | VAF 14/340 reads (4%) | called by muse, mutect2
- ZDHHC7 | c.*17C>G | 3'UTR (SNP) | VAF 46/348 reads (13%) | called by muse, mutect2, varscan2
- ZNF16 | c.196+62C>G | Intron (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
